Somatic mutation profile of tumor specimen MMRF_1695_1_BM_CD138pos (aliquot MMRF_1695_1_BM_CD138pos_T1_KBS5U_L04783) from MMRF case MMRF_1695, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.4 years (22,436 days).
Specimen MMRF_1695_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fda18170-b963-4a5e-a6cc-f1eb70d9f034.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1695_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1695_1_PB_Whole_C3_KBS5U_L04796; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8a063b0-3521-4f8c-ac13-4ad087d03501

The open-access MAF lists 61 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 16, Silent 11, Intron 6, 3'Flank 4, 5'UTR 3, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP135 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs141788521; called by muse, mutect2, varscan2
- ORMDL3 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1397534813; called by muse, mutect2, varscan2
- SPTBN4 | c.5440G>A p.E1814K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58957727; called by muse, mutect2, varscan2
- UTRN | c.2317C>G p.L773V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV62333944; called by muse, varscan2
- ABCF3 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- ACTG1 | c.249_290del p.E83_A97delinsD | In Frame Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel
- AGBL1 | c.506T>G p.L169W | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.14047G>T p.D4683Y | Missense Mutation (SNP) | VAF 132/252 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- BEND7 | c.1202A>G p.E401G | Missense Mutation (SNP) | VAF 36/153 reads (24%) | PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSRNP3 | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KCNH8 | c.969+6T>C | Splice Region (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- LRRN1 | c.502A>T p.N168Y | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- RXFP3 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIT2 | c.1447C>G p.Q483E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.779); called by muse, varscan2
- SYBU | c.1771A>C p.I591L (on ENST00000276646 / NM_001099754.2; = p.I590L on NM_017786.6) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF4 | c.990+8_990+15del | Splice Region (DEL) | VAF 65/152 reads (43%) | called by mutect2, pindel, varscan2
- TNXB | c.8323C>A p.L2775M (on ENST00000647633; = p.L2528M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TRIP12 | c.5660A>G p.H1887R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- UGT3A1 | c.494T>G p.I165S | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- WRNIP1 | c.715T>G p.Y239D | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ZNF223 | c.864C>G p.F288L | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACTL9 | c.1146C>T p.I382= | Silent (SNP) | VAF 67/114 reads (59%) | catalogued as COSV61006667; called by muse, mutect2, varscan2
- ARHGEF38 | c.1155G>A p.Q385= | Silent (SNP) | VAF 76/249 reads (31%) | catalogued as rs1191662704; called by muse, mutect2, varscan2
- ERMP1 | c.84G>A p.P28= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs1216632036; called by muse, mutect2, varscan2
- HIP1 | c.2043C>T p.C681= | Silent (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.228C>T p.I76= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs368264920; called by muse, varscan2
- IGLV3-10 | c.120C>T p.T40= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- KIF5C | c.516G>A p.R172= | Silent (SNP) | VAF 49/178 reads (28%) | catalogued as rs1339655793; called by muse, mutect2, varscan2
- LRP1B | c.6675A>C p.I2225= | Silent (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- MORC1 | c.454A>C p.R152= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- SDC3 | c.763C>A p.R255= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV59581159; called by muse, mutect2, varscan2
- UTP15 | c.1377T>C p.V459= | Silent (SNP) | VAF 50/203 reads (25%) | catalogued as COSV57146125; called by muse, mutect2, varscan2
- ACTG1 | c.363+105G>A | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as rs782794232; called by muse, mutect2, varscan2
- ACTRT1 | c.-114T>G | 5'UTR (SNP) | VAF 21/31 reads (68%) | catalogued as COSV64418900; called by muse, mutect2, varscan2
- ADSS2 | c.*420A>G | 3'UTR (SNP) | VAF 9/24 reads (38%) | catalogued as rs999426115; called by muse, mutect2, varscan2
- AKT1S1 | c.*651T>G | 3'UTR (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF6 | c.*1786del | 3'UTR (DEL) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- ARL10 | c.*2391G>T | 3'UTR (SNP) | VAF 30/147 reads (20%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948599 T>G | 3'Flank (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- CDH8 | c.*556A>C | 3'UTR (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- CELF4 | c.-33C>T | 5'UTR (SNP) | VAF 27/66 reads (41%) | catalogued as rs763089811; called by muse, mutect2, varscan2
- CHRM2 | chr7:137017444 T>C | 3'Flank (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- CSMD3 | c.*1753A>C | 3'UTR (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- DENND2B | c.-25-6371C>G | Intron (SNP) | VAF 44/183 reads (24%) | called by muse, mutect2, varscan2
- DSCAM | c.-356G>A | 5'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- FAH | c.82-86C>G | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- GRIN2A | c.*725G>A | 3'UTR (SNP) | VAF 18/76 reads (24%) | catalogued as rs1329809128; called by muse, mutect2, varscan2
- HEG1 | c.*4398G>A | 3'UTR (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- INO80D | c.*6667G>A | 3'UTR (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- ITGA8 | c.*2444T>A | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- JPH3 | c.2167-510T>G | Intron (SNP) | VAF 10/42 reads (24%) | catalogued as COSV52474249; called by muse, mutect2
- ODR4 | c.*1346G>T | 3'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- PAX3 | chr2:222201055 G>A | 3'Flank (SNP) | VAF 29/103 reads (28%) | catalogued as rs536679300; called by muse, mutect2, varscan2
- SDC1 | c.*1925T>C | 3'UTR (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- SLC19A2 | c.*1428T>C | 3'UTR (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- SLIRP | c.*37A>G | 3'UTR (SNP) | VAF 69/248 reads (28%) | called by muse, mutect2, varscan2
- SPIN2A | chrX:57134849 T>C | 3'Flank (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- SYBU | c.*6A>G | 3'UTR (SNP) | VAF 52/211 reads (25%) | called by muse, mutect2, varscan2
- TAGLN | c.-12-567A>T | Intron (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- TMEM108 | c.1451-2167T>A | Intron (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- TMEM268 | c.*2565T>A | 3'UTR (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
